Surgical pathology report (de-identified scan), TCGA case TCGA-14-1829, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1829-01A (Primary Tumor).

[page 1 of 7]
AP Report

* Final Report *

Document Type: AP Report
Document Date: [REDACTED]
Document Status: Modified
Document Title: AP REPORT
Encounter info: [REDACTED]

TCGA-14-1829

* Final Report *

AP REPORT

Patient: [REDACTED] Accession Number: [REDACTED]
Patient Number: [REDACTED] Date Collected: [REDACTED]
Financial Number: [REDACTED] Date Received: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

SUPPLEMENTAL REPORT

SUPPLEMENTAL DIAGNOSIS:

Previous diagnosis remains unchanged.

COMMENT:

This test was not requested, performed or reported at [REDACTED]
Hospital Department of Pathology.

The test was requested by [REDACTED] The test was performed and results
reported by [REDACTED]

Results are included with this Surgical Pathology report so that all available
information on this tumor may be accessed at one site.

MGMT GENE AMPLIFICATION

DNA was isolated from a paraffin embedded block of the brain tumor biopsy
[REDACTED] DNA methylation patterns in the CpG island of the MGMT gene
(Genebank accession number [REDACTED] was determined by chemical
(bisulfite) modification of unmethylated, but not methylated, cytosines to

Printed by:
Printed on:

Page 1 of 8
(Continued)

[page 2 of 7]
AP Report

* Final Report *

TCGA-14-1829

uracil and subsequent PCR using primers specific for either methylated or the modified unmethylated DNA (). The PCR products were analyzed in duplicate parallel runs by capillary gel electrophoresis. The sensitivity of the assay based on DNA dilution studies is at least 1:1000.

RESULT:

The analyzed region of the MGMT promoter is UNMETHYLATED.

INTERPRETATION:

MGMT (O6 methylguanine DNA methyltransferase) is a DNA repair gene. Methylation of the promoter leads to gene silencing and loss of MGMT expression. A recent study that tested the methylation status of the same region of the MGMT promoter in glioblastomas found that MGMT promoter methylation was an independent favorable prognostic factor and was associated with a survival benefit in patients treated with temozolamide and radiotherapy.

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT TEMPORAL BRAIN LESION, BIOPSY, FS1A, TP1A:
- GLIOBLASTOMA WITH OLIGODENDROGLIAL COMPONENT (WHO GRADE IV).
- SEE COMMENT.
2. LEFT TEMPORAL BRAIN LESION, EXCISION:
- GLIOBLASTOMA WITH OLIGODENDROGLIAL COMPONENT (WHO GRADE IV).
- SEE COMMENT.

COMMENT:

Sections show fragments of tumor composed of cells of both astrocytic and oligodendroglial morphology. Microvascular proliferation, mitoses and

Page 1 (Continued...)

Printed by:
Printed on:

Page 2 of 8
(Continued)

[page 3 of 7]
AP Report

* Final Report *

TCGA-14-1829

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

SURGICAL PATHOLOGY REPORT

COMMENT:

necrosis are present. Taken together, these findings are diagnostic for glioblastoma with an oligodendroglial component. Fluorescent in situ hybridization (FISH) for loss of heterozygous of chromosomes 1P and 19Q, and amplification of epidermal growth factor receptor (EGFR) will be performed and reported as an addendum to this report. MGMT Promotor Methelation Analysis will be sent to an outside laboratory, and results will be addended to this report.

SPECIMEN:

1. Left temporal brain lesion.
2. Left temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Craniotomy for tumor (L). Brain lesion.

GROSS DESCRIPTION:

Two specimens are received, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation and designated "left temporal brain lesion." The specimen consists of multiple fragments of soft gray tissue measuring 2.5 x 1.5 x 0.5 cm in aggregate. Representative tissue is submitted for frozen section diagnosis and the contents of the cryoblock are transferred to cassette "FS1A." A touch preparation is made. The remainder of the specimen is submitted entirely in cassette "1B."

Specimen #2 is received in formalin and labeled as "left temporal brain lesion." The specimen consists of multiple fragments of brain tissue measuring 5.0 x 5.0 x 1.5 cm in aggregate. Representative sections are submitted in cassettes "2A" through "2F." [REDACTED] [REDACTED]

Printed by:
Printed on:

Page 3 of 8
(Continued)

[page 4 of 7]
AP Report

* Final Report *

TCGA-14-1829

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: LEFT TEMPORAL BRAIN LESION, BIOPSY (FROZEN SECTION, TOUCH
PREPARATION): GLIOBLASTOMA.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

The pathologist has reviewed and interpreted the case with the
resident/fellow.

SPECIAL STAINS:

FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE
FISH	DONE

Page 2 (Continued...)

Patient:
Patient Number:

Accession Number:

FLUORESCENCE IN SITU HYBRIDIZATION

Printed by:
Printed on:

Page 4 of 8
(Continued)

[page 5 of 7]
AP Report

* Final Report *

TCGA-14-1829

SPECIMEN:

Brain, left temporal lesion.

CLINICAL HISTORY/REFERRING DIAGNOSIS:

Glioblastoma with oligodendroglial component (WHO Grade IV).

GROSS DESCRIPTION:

Paraffin block 1B.

TEST PERFORMED/PROBES USED:

Probe for chromosome 1p36

Probe for chromosome 1q25

Probe for chromosome 19p13

Probe for chromosome 19q13

EGFR gene locus specific probe(7p12)

Chromosome 7 alpha satellite DNA specific probe(7p11.1-7q11.1)

RESULTS:

POSITIVE for chromosome 1p36 deletion

nuc ish 1p36(1P36 x 1),1q25(1Q25 x 2)[152/200]

POSITIVE for chromosome 19q13 deletion

nuc ish 19p13(19P13 x 2),19q13(19Q13 x 1)[126/200]

POSITIVE for EGFR gene amplification

nuc ish amp(EGFR)[200/200]

Printed by:
Printed on:

Page 5 of 8
(Continued)

[page 6 of 7]
[REDACTED]

AP Report

* Final Report *

[REDACTED]

TCGA-14-1829

Page 3 (Continued...)

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION

INTERPRETATION:

Fluorescence in situ hybridization was performed using the above listed DNA probes (Vysis Inc.). The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 24% demonstrated loss of signal for the

Printed by:
Printed on:

Page 6 of 8
(Continued)

[page 7 of 7]
AP Report

* Final Report *

TCGA-14-1829

1p36 probe which indicates the presence of deletion for chromosome 1p36. Correlation with clinical and other laboratory parameters is suggested.

Fluorescence in situ hybridization was performed using the above listed DNA probes (). The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 13% demonstrated loss of signal for the 19q13 probe which indicates the presence of deletion for chromosome 19q13. Correlation with clinical and other laboratory parameters is suggested.

Fluorescence in situ hybridization was performed using the above listed DNA probes (). The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 100% of cells were POSITIVE for EGFR gene amplification. Positive and negative controls were appropriate. Correlation with clinical and other laboratory parameters is suggested.

This test was developed and its performance characteristics determined by the Emory medical Laboratories. It has not been cleared or approved by the U.S. food and Drug Administration.

The results of this test should not be used alone as the sole basis for diagnosis and/or treatment. These results may, however, prove useful when used in conjunction with other diagnostic procedures and clinical evaluations. Use of these results, in this manner, can be considered to fall within the scope of practice of medicine. This test was developed and its performance characteristics determined by the (). It has not been cleared or approved by the U.S. Food and Drug Administration.

COMMENT:

See above.

Printed by:
Printed on:

Page 7 of 8
(Continued)

Source: NCI Genomic Data Commons file 49cdbeb9-25ca-40de-9377-2357a085e98e (TCGA-14-1829.A56C7808-D310-4D94-B0FA-5FCF5289555D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).